Surgical pathology report (de-identified scan), TCGA case TCGA-24-1469, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1469-01A (Primary Tumor).

[page 1 of 5]
**SURGICAL PATHOLOGY REPORT
FINAL WITH ADDENDUM**

Patient Name:

Address:

Gender:

DOB:

Service:

Location:

MRN :

Hospital #:

Patient Type:

Accession #:

Taken:

Received:

Accessioned:

Reported:

Physician(s):

DIAGNOSIS:

OVARY, RIGHT, SALPINGO-OOPHORECTOMY

- SEROUS ADENOCARCINOMA, POORLY DIFFERENTIATED (SEE COMMENT)
- GREATEST DIMENSION 10 CM
- SURFACE TUMOR DEPOSITS PRESENT
- SEE SYNOPTIC REPORT

FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY

- SEROUS ADENOCARCINOMA INVOLVING THE SURFACE, WALL (INTRAMURAL DEPOSIT), AND LUMINAL EPITHELIUM OF THE FALLOPIAN TUBE
- HYDROSALPINX

UTERUS, SEROSA, TOTAL ABDOMINAL HYSTERECTOMY

- METASTATIC SEROUS ADENOCARCINOMA

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- SEROUS ADENOCARCINOMA, BY DIRECT EXTENSION OF SEROSAL TUMOR
- LEIOMYOMATA
- ADENOMYOSIS

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- INACTIVE ENDOMETRIUM

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY

- NO EVIDENCE OF MALIGNANCY

OVARY, LEFT, SALPINGO-OOPHORECTOMY

- NO EVIDENCE OF MALIGNANCY

FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY

- NO EVIDENCE OF MALIGNANCY

LARGE INTESTINE RECTOSIGMOID, EXCISION

- METASTATIC SEROUS ADENOCARCINOMA, INVOLVING SEROSA AND PERICOLONIC FAT (LARGEST TUMOR NODULE 3.3 CM)
- DIVERTICULOSIS
- MARGINS OF RESECTION VIABLE AND FREE OF MALIGNANCY

[page 2 of 5]
OMENTUM, BIOPSY (FS1)

- METASTATIC SEROUS ADENOCARCINOMA (4.4 CM)

OMENTUM, GASTROCOLIC, EXCISION

- METASTATIC SEROUS ADENOCARCINOMA

LYMPH NODES, PERICOLONIC, EXCISION

- NO EVIDENCE OF MALIGNANCY IN SEVEN LYMPH NODES (0/7)

LARGE INTESTINE, RECTOSIGMOID RE-ANASTOMOTIC RINGS, EXCISION

- NO EVIDENCE OF MALIGNANCY

Intraoperative Consultation:

FS1: Omental tumor, biopsy

- "Poorly differentiated adenocarcinoma, favor Mullerian," by

Microscopic Description and Comment:

Sections of the right ovary show tumor adjacent to fibromuscular stroma and thick wall vessels, suggesting that the extends into the periadnexal soft tissue.

History:

Operative procedure: Exploratory laparotomy, total abdominal hysterectomy, bilateral salpingo-oophorectomy, rectosigmoid resection, omentectomy.

Specimen(s) Received:

A: GASTRO-COLIC OMENTUM

B: OMENTUM

C: RIGHT FALLOPIAN TUBE AND RIGHT OVARY

D: LEFT FALLOPIAN TUBE, LEFT OVARY, UTERUS, AND CERVIX

E: RECTO-SIGMOID COLON

F: COLON, RE-ANASTOMOTIC DONUT

Gross Description:

The specimens are received in six formalin-filled containers labeled [REDACTED]. The first container is labeled "gastrocolic omentum." It contains a 36 x 10 x 1.2 cm piece of yellow-tan omentum. There is a previously incised 4 x 2.6 x 1.7 cm firm white mass with irregular borders within the omentum. There is a separate 2.7 x 2.1 x 1.4 cm nodule of firm white tissue infiltrating through yellow adipose tissue. Finally, a 0.4 cm diameter firm white nodule

[page 3 of 5]
SURGICAL PATHOLOGY REPORT

with an irregular border is identified. The remaining omentum is comprised of unremarkable yellow-tan fibrofatty tissue. Labeled A1 - largest nodule. Jar 2.

The second container is labeled "omentum tumor, FS1/X." It contains a cassette labeled "FS1" that holds a 2.4 x 1.7 x 0.2 cm piece of white-yellow tissue. Labeled B1 (FS1) Also in the container is a previously incised 4.4 x 3.8 x 2.7 cm piece of yellow-tan fibroadipose tissue, largely replaced by a 4.4 x 2.9 x 2.9 cm white nodule with irregular borders. Labeled B2. [REDACTED]

The third container is labeled "right fallopian tube and ovary." It contains a 10.0 x 7.8 x 5.4 cm tan-purple mass. The surface shows hemorrhage, multiple adhesions, and adherent fat. Also on the surface is a 10.0 x 4.7 cm area covered by an exophytic white-yellow tumor. No definitive fallopian tube is identified. Sections show an 8 cm long dilated tube-like structure, with a lumen diameter that ranges from 0.6 to 3.0 cm. No fimbriated end is identified. The tube is lined by smooth white-pink tissue with adherent clot. The mass is otherwise comprised of solid and cystic tissue, with the largest solid component measuring 10.0 x 3.5 x 3.4 cm. The cystic component is lined by tan-white tissue, with multiple small tan-brown excrescences. Sections of the cyst wall show a 3.6 x 2.1 x 0.5 cm area with firm white tissue that may represent compressed ovarian stroma. Labeled C1 to C3 - solid portion of tumor, with surface involvement; C4 - cyst wall, with putative compressed ovarian parenchyma; C5 and C6 - cystic and solid portion of tumor; C7 and C8 - putative fallopian tube. [REDACTED]

The fourth container is labeled "left fallopian tube, ovary, cervix, and uterus." It contains a 96 gram, 8.5 (superior to inferior) x 4.7 (cornu to cornu) x 4.0 cm (anterior to posterior) tan-pink uterus and cervix, with attached left ovary and fallopian tube. The 2.9 x 2.8 cm ectocervix shows multiple Nabothian cysts, and hemorrhage, but is otherwise covered by shiny white mucosa. There is an adjacent 0.2 - 1.2 cm wide rim of vaginal mucosa. The 0.3 cm external os is unremarkable. The serosa and myometrium have been incised at the posterior fundus, for a length of 2.9 cm. The peritoneum over the anterior uterine fundus and lower uterine segment show a 2.7 x 1.4 x 0.3 cm area of papillary tan tissue consistent with tumor implant. Similar tan tissue is seen at the serosa over the right cornu. Several small serosal implants are seen posteriorly. The uterus and cervix are opened to show a 3.0 cm long x 0.4 cm diameter endocervical canal, lined by white-tan mucosa. The 3.1 cm long x 1.5 cm wide endometrial cavity is lined by thin tan and hemorrhagic endometrium. Sections of the cervix show multiple Nabothian cysts. Sections of the endomyometrium show an endometrial thickness of 0.1 cm. There is a well circumscribed 1.1 cm diameter firm, calcified nodule in the myometrium anteriorly, consistent with an intramural fibroid. The 3.9 x 1.2 x 0.8 cm white-tan ovary has a smooth surface. The adjacent 5.7 cm long x 0.7 cm diameter purple-tan fallopian tube has a smooth surface and an unremarkable fimbriated end. Sections of the ovary show unremarkable white-tan tissue. Sections of the fallopian tube show an unremarkable pinpoint lumen, and a 0.7 cm diameter thin walled paratubal cyst. Labeled D1- anterior cervix; D2- anterior lower uterine segment and fundus, with intramural fibroid and anterior serosal tumor implant (acid decalcification); D3 - posterior cervix; D4 - posterior lower uterine segment with serosal tumor implant; D5 - posterior fundus; D6 - anterior myometrium and serosa, with serosal tumor implant; D7 - left ovary; D8 - left fallopian tube. [REDACTED]

The fifth container is labeled "rectosigmoid." It contains a 21.5 cm long x 3.7 cm diameter segment of sigmoid and rectum. A staple line is present at each margin. The pericolic fat is thickened, with adherent tan-brown tissue consistent with tumor implants, measuring up to 3.3 cm in greatest dimension. The staple lines are excised, and the colon opened to show light tan mucosa, without lesions. There is a 2.5 cm long narrowed segment in the mid portion of the specimen, with a luminal diameter of 1.4 cm, compared to a luminal diameter of 2.0 cm surrounding the stricture. Sections of the sigmoid show a 0.7 cm intact diverticulum. There is no gross involvement by the tumor of the muscularis or the colonic mucosa. Sections of the pericolonic fat show multiple white-tan tumor nodules, measuring up to 5.5 cm in greatest dimension. Three small white nodules are identified within the fat that may represent lymph node metastasis, ranging from 0.3 to 0.4 cm. Also identified are several pink-tan benign-appearing lymph nodes, measuring up to 0.5 cm in diameter. Labeled E1 - proximal margin; E2 - distal margin; E3 - stricture; E4 - diverticulum; E5 - largest tumor nodule; E6 - small tumor nodules within pericolic fat; E7 to E9 - lymph nodes. Jar 3.

The sixth container is labeled "re-anastomotic donut." it contains two pieces of tan mucosa and attached soft tissue, measuring 0.9 cm in length x 1.7 cm in diameter and 0.8 cm in length x 1.9 cm in diameter, respectively. Both contain surgical staples. The mucosa shows hemorrhage, but not lesions. Labeled F1 and F2. [REDACTED]

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

[page 4 of 5]
HISTOPATHOLOGIC TYPE

The histologic diagnosis is serous adenocarcinoma

TUMOR LOCATION

The location of the primary tumor is the right ovary only

HISTOLOGIC GRADE

The histologic grade is poorly differentiated (G3)

TUMOR INVASION

Tumor is identified on the ovarian surface and invades the adjacent fallopian tube/peritubal soft tissue

TUMOR INVOLVEMENT

Tumor involvement of the pelvic peritoneum/soft tissue is present, and metastatic involvement of the omentum is present

TUMOR SIZE

The maximum dimension of tumor implants outside the true pelvis is greater than or equal to 2 cm

PRIMARY TUMOR (T)

Based on the above information, the primary tumor is classified as macroscopic peritoneal metastasis beyond pelvis more than 2 cm in greatest dimension or regional lymph node metastasis (T3c/IIIC)

REGIONAL LYMPH NODES (N)

The regional lymph nodes cannot be assessed (NX)

DISTANT METASTASIS (M)

No distant metastases reportedly present (M0)

STAGE GROUPING

The Final AJCC/UICC/FIGO stage is T3c/NX/M0

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Addenda/Procedures

Addendum Diagnosis

OVARY, RIGHT, SALPINGO-OOPHORECTOMY

- SEROUS ADENOCARCINOMA, POORLY DIFFERENTIATED (SEE COMMENT)
- GREATEST DIMENSION 10 CM
- SURFACE TUMOR DEPOSITS PRESENT
- SEE SYNOPTIC REPORT

FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY

- SEROUS ADENOCARCINOMA INVOLVING THE SURFACE, WALL(INTRAMURAL DEPOSIT), AND LUMINAL EPITHELIUM OF THE FALLOPIAN TUBE
- HYDROSALPINX

UTERUS, SEROSA, TOTAL ABDOMINAL HYSTERECTOMY

- METASTATIC SEROUS ADENOCARCINOMA

[page 5 of 5]
SURGICAL PATHOLOGY REPORT

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- SEROUS ADENOCARCINOMA, BY DIRECT EXTENSION OF SEROSAL TUMOR
- LEIOMYOMATA
- ADENOMYOSIS

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- INACTIVE ENDOMETRIUM

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY

- NO EVIDENCE OF MALIGNANCY

OVARY, LEFT, SALPINGO-OOPHORECTOMY

- NO EVIDENCE OF MALIGNANCY

FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY

- NO EVIDENCE OF MALIGNANCY

LARGE INTESTINE RECTOSIGMOID, EXCISION

- METASTATIC SEROUS ADENOCARCINOMA, INVOLVING SEROSA AND PERICOLONIC FAT (LARGEST TUMOR NODULE 3.3 CM)
- DIVERTICULOSIS
- MARGINS OF RESECTION VIABLE AND FREE OF MALIGNANCY

OMENTUM, BIOPSY (FS1)

- METASTATIC SEROUS ADENOCARCINOMA (4.4 CM)

OMENTUM, GASTROCOLIC, EXCISION

- METASTATIC SEROUS ADENOCARCINOMA

LYMPH NODES, PERICOLONIC, EXCISION

- NO EVIDENCE OF MALIGNANCY IN SEVEN LYMPH NODES (0/7)

LARGE INTESTINE, RECTOSIGMOID RE-ANASTOMOTIC RINGS, EXCISION

- NO EVIDENCE OF MALIGNANCY

Addendum Comment

A decalcified section of the anterior lower uterine segment shows a calcified leiomyoma. There is metastatic serous adenocarcinoma involving the uterine serosa, with direct extension to the myometrium. There is no change in the final diagnosis or in the tumor stage.

Source: NCI Genomic Data Commons file 42cecf56-75d2-41da-bbb0-2616133228b0 (TCGA-24-1469.8F0B80D0-CF56-477C-898B-BB92934F64D4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).